Somatic mutation profile of tumor specimen MP2PRT-PATWZV-TMP1-A (aliquot MP2PRT-PATWZV-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PATWZV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,136 days).
Specimen MP2PRT-PATWZV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d8b8e89-6dd7-4a49-8292-1a69f37e5e5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWZV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWZV-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67c633cf-872d-48d5-9e7e-e4e3f14d197f

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 4, Intron 2, 5'UTR 1, Frame Shift Ins 1, In Frame Ins 1, Splice Region 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.3302A>G p.E1101G | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs782663402; called by muse, mutect2, varscan2
- CNTN1 | c.2093G>A p.R698K | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104417999; called by muse, mutect2, varscan2
- CXXC1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53276643; called by muse, mutect2, varscan2
- FAT3 | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 28/385 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as rs199580154; called by muse, mutect2
- IDO1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 32/258 reads (12%) | catalogued as rs1173666738; called by muse, mutect2, varscan2
- JAK1 | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV61089652; called by muse, mutect2, varscan2
- PAPLN | c.1774C>T p.R592* (on ENST00000554301; = p.R565* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 227/627 reads (36%) | catalogued as rs145637886; called by muse, mutect2, varscan2
- PLPPR2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 64/577 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs766533759; called by muse, mutect2, varscan2
- PRDM16 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 248/711 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs1012036612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM9 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1399820378; called by muse, mutect2, varscan2
- STAC3 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 16/232 reads (7%) | catalogued as rs1202215410; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.24154G>A p.V8052I (on ENST00000591111; = p.V7125I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/216 reads (11%) | PolyPhen benign (0); catalogued as rs755722481, COSV60116396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF521 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 129/348 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.105); catalogued as rs116142901; called by muse, mutect2, varscan2
- ZNF544 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 29/434 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV54138414, COSV99517140; called by muse, mutect2
- CRTC1 | c.126G>C p.R42= | Splice Region (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- GFY | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 50/586 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2
- IGHV1-69 | c.348_350delinsCCTGGA p.R117delinsLE | In Frame Ins (INS) | VAF 27/62 reads (44%) | called by muse*, pindel
- OTUD1 | c.1208_1209insT p.T404Hfs*18 | Frame Shift Ins (INS) | VAF 128/385 reads (33%) | called by mutect2, pindel, varscan2
- TAS1R3 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 44/485 reads (9%) | called by muse, mutect2
- SCRT2 | c.510G>C p.L170= | Silent (SNP) | VAF 40/525 reads (8%) | called by muse, mutect2
- GPR35 | c.-78C>T | 5'UTR (SNP) | VAF 119/358 reads (33%) | catalogued as rs557586396; called by muse, mutect2, varscan2
- HAGHL | c.397+14G>A | Intron (SNP) | VAF 42/504 reads (8%) | called by muse, mutect2
- HAGHL | c.397+15G>A | Intron (SNP) | VAF 43/507 reads (8%) | called by muse, mutect2
- MIR296 | chr20:58819042 C>T | 5'Flank (SNP) | VAF 43/413 reads (10%) | catalogued as rs778004353; called by muse, mutect2, varscan2
